Surgical pathology report (de-identified scan), TCGA case TCGA-RG-A7D4, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Montefiore Medical Center, specimen TCGA-RG-A7D4-01A (Primary Tumor).

[page 1 of 3]
ICD.O-3 Carcinoma,
hepatocellular NOS
8/7/13

Date Liver C22.0

9/5/2013

Patient Name: UID:C8724B8E-5FC3-419B-9CC8-E6046D671D96
Requested By:
Ordered By:

Report Name:

Surg Path Case - STATUS: Final

**SEE NOTE

Collect/Perform:

Ordered By:

Ordered Date:

Facility:

Department: PATH

Physician Who Performed Procedure:

Requesting Physician: Not specified

SURGICAL PATHOLOGY,

CASE#: [REDACTED]

Attending Pathologist

DIAGNOSIS:

Liver, central hepatectomy:

- Histologic Type: Hepatocellular carcinoma
- Histologic Grade: G2 (moderately differentiated) to G3 (poorly differentiated)
- Tumor Size:
- Greatest dimension: 2.8 cm; other two dimensions: 2.4 x 2.2 cm
- Tumor Focality: Solitary
- Tumor Site: Segment 4b of the liver (by MRI report)
- Tumor Extension: Tumor confined to liver
- Margins:
- Parenchymal Margin: Uninvolved by invasive carcinoma
- Distance of invasive carcinoma from closest margin: 1 mm to 2 mm from parenchymal resection margin
- Other margins: Cannot be assessed
- Lymph-Vascular Invasion:
- Macroscopic Venous (Large Vessel) Invasion: Not identified
- Microscopic (Small Vessel) Invasion: Present
- Perineural Invasion: Not identified
- Regional Lymph Nodes (total number involved/total number identified): 0/2 (part 2)
- Distant Metastasis: Cannot be assessed
- Additional Pathologic Findings: Liver parenchyma shows portal inflammatory infiltrate, predominantly lymphocytes, with mild interface activity, and portal and periportal fibrosis with some bridging fibrosis (3/6, trichrome and reticulin stains), consistent with chronic hepatitis (clinical history of hepatitis C virus infection). No significant hemosiderosis (iron stain) and no globules of alpha-1 antitrypsin seen (PASD stain). Small bile duct hamartoma (von. Mayenburg complex, 1mm in

[page 2 of 3]
Patient Name: [REDACTED]

Med Rec #: [REDACTED]

Requested By:

Ordered By:

Report Name: :

largest dimension) seen.

Fibrosis score: None to moderate fibrosis (Ishak score 0-4) (F0)

Hepatocellular dysplasia: Not identified

- Ancillary Studies: None

- Clinical History: Hepatitis C virus infection

AJCC Pathologic Staging: pT2 N0 M-not applicable

2. Gallbladder, cholecystectomy:

- Chronic cholecystitis with cholelithiasis and cholesterosis.

- Two lymph nodes, negative for carcinoma (0/2).

COMMENT: None

This case has been reviewed by one or more pathologists in the Division of Surgical Pathology.

CLINICAL INFORMATION:

Liver Cancer

GROSS DESCRIPTION:

1. The specimen is received fresh for intraoperative consult labeled "central hepatectomy". It consists of a 57 g, 7.0 x 4.4 x 2.8 cm wedge-shaped piece of liver. The capsule is smooth and glistening. The parenchymal margin is inked black. Sectioning reveals a well-circumscribed, nodular, tan tumor, measuring 2.8 x 2.4 x 2.2 cm and located 0.1 cm from the capsule and 0.2 cm from the parenchymal margin. The surrounding liver parenchyma is tan and grossly unremarkable with cauterized areas. Representative sections are submitted as follows:

1AFSC: Liver tumor with parenchymal margin, frozen

1B-1E: Additional sections of liver tumor with parenchymal margin and capsule

1F: Grossly uninvolved liver

INTRAOPERATIVE CONSULT:

- Focally tumor is 1 to 2 mm to inked parenchymal margin.

Reported to

102 of 3

[page 3 of 3]
Patient Name: [REDACTED]

Med Rec #: [REDACTED]

Requested By:

Ordered By:

Report Name:

Pathology consult:

2. The specimen is received fresh and labeled "Gallbladder" and consists of a previously cut gallbladder, measuring 6.6 x 3.0 x 1.2 cm. The serosa is tan-pink with fibrous adhesion. Sectioning reveals a minimal amount of bile and a 0.7 x 0.6 x 0.5 cm black calculus. The mucosa is erythematous with minimal focal yellow flecks. The wall measures up to 0.3 cm thick. The proximal portion of the cystic duct is identified and contains no stones in its lumen, which measures up to 0.2 cm in diameter. There are two firm lymph nodes adjacent to the cystic duct and measuring 1.4 x 0.6 x 0.6 cm and 1.5 x 0.8 x 0.7 cm. Sections are submitted as follows:

2A: inked shaved cystic duct margin and sections of gallbladder

2B: Two bisected lymph nodes (differentially inked black and blue)

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

1xIRON (NOT BM ASPIRATE), 1xTRICHROME-MASSON, 1xRETICULIN, 1xPAS-DIASTASE

** Electronic Signature **

**Electronically Signed Out by

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the final diagnosis(es).

Note: The histology, immunochemistry and in situ hybridization components for this case were performed at

The Attending Pathologist reviewed this case and made the diagnosis.

Where applicable, immunohistochemistry and in situ hybridization tests were developed and the performance characteristics determined by the

These tests have not been cleared or approved by the US Food and Drug Administration and the results should be correlated with other clinical and laboratory data. Appropriate controls were performed for all immunohistochemistry, in situ hybridization and histochemical tests.

Pg 3 of 3

Source: NCI Genomic Data Commons file d84c38c9-9d02-4b01-9071-40228ee3d08c (TCGA-RG-A7D4.C8724B8E-5FC3-419B-9CC8-E6046D671D96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).